Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAHF, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-2G-AAHF-01A (Primary Tumor).

Department of Pathology

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Postal address

Street address

Summary pathology report

Right orchidectomy; seminoma; diameter 6.0 cm; no angio-invasion present; no invasion in rete testis; no invasion of tunica albuginea; epididymis free of tumor; surgical margin of spermatic cord free of tumor.

Date of procurement (= date of orchidectomy):

ICD O-3
Seminoma NOS 9061/3
Site [®] Testis NOS C62.9
pJ 3/7/14

pathologist

professor of pathology

W 1/8/14

Source: NCI Genomic Data Commons file 35c8e633-b2b4-4aa0-b00a-e85a454b0f22 (TCGA-2G-AAHF-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).